Somatic mutation profile of tumor specimen TCGA-EJ-7315-01A (aliquot TCGA-EJ-7315-01A-31D-2114-08) from TCGA case TCGA-EJ-7315, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.9 years (25,154 days).
Specimen TCGA-EJ-7315-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27fd7599-39ce-4e9d-b9a1-cafbf60fa692.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7315-10A (Blood Derived Normal), aliquot TCGA-EJ-7315-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78b4731a-e507-4409-8591-2744b0d92a8d

The open-access MAF lists 21 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 16, Silent 3, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1057T>A p.Y353N | Missense Mutation (SNP) | VAF 26/71 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV61685455, COSV61692205, COSV61693488; called by muse, mutect2, varscan2
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANGPTL6 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs769478685, COSV53463224; called by muse, mutect2, varscan2
- CCDC197 | c.80A>G p.Q27R | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1438375340, COSV58939813; called by muse, mutect2, varscan2
- CLSTN2 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs137889465; called by muse, mutect2, varscan2
- DMAP1 | c.332T>G p.F111C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60001454; called by muse, mutect2
- EDC4 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs780356438, COSV54647003; called by muse, mutect2, varscan2
- ELOVL4 | c.899T>A p.I300K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV63954379; called by muse, mutect2, varscan2
- ERBB4 | c.2779C>T p.R927* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as rs537458255, COSV61460348; called by muse, mutect2, varscan2
- HSPA4 | c.1481G>A p.S494N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs141758444; called by muse, mutect2, varscan2
- KIDINS220 | c.3787T>G p.F1263V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56757301; called by muse, mutect2, varscan2
- NLRP10 | c.1474C>T p.R492C | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1337384075, COSV60781578; called by muse, mutect2, varscan2
- P2RY4 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.534); catalogued as rs779083147, COSV65736999; called by mutect2, varscan2
- RSC1A1 | c.1294A>G p.T432A | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs1255175967, COSV60780754; called by muse, mutect2, varscan2
- RYR2 | c.7570G>A p.V2524I | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.266); catalogued as rs934248102, COSV63687294; called by muse, mutect2, varscan2
- SLC30A6 | c.730T>C p.Y244H | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs1314869672, COSV50873631; called by muse, mutect2, varscan2
- TRHR | c.1163G>T p.C388F | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV61235799; called by muse, mutect2, varscan2
- TTLL12 | c.342dup p.N115Qfs*38 | Frame Shift Ins (INS) | VAF 17/52 reads (33%) | catalogued as rs34872708; called by mutect2, pindel, varscan2
- CHST2 | c.1299C>G p.V433= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs1435419888, COSV58886546; called by muse, mutect2, varscan2
- CTAG2 | c.177C>T p.G59= | Silent (SNP) | VAF 13/15 reads (87%) | catalogued as rs1557241811, COSV55996219; called by muse, mutect2, varscan2
- GTF3C1 | c.2493G>A p.T831= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as rs754307325, COSV62240516; called by mutect2, varscan2
